Somatic mutation profile of tumor specimen MMRF_1383_1_BM_CD138pos (aliquot MMRF_1383_1_BM_CD138pos_T1_KAS5U_L00685) from MMRF case MMRF_1383, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 73.6 years (26,900 days).
Specimen MMRF_1383_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b59ce3c7-1ddc-49a9-a141-ec83c9fcc362.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1383_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1383_1_PB_Whole_C2_KAS5U_L00693; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5e87979-4930-4bdf-870a-ca180c8c5ab4

The open-access MAF lists 117 somatic variants for this specimen: 48 protein-altering or splice-affecting, 13 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, 3'UTR 21, Intron 16, Silent 13, 5'UTR 7, 5'Flank 5, 3'Flank 4, Frame Shift Del 3, RNA 3, Nonsense Mutation 2, In Frame Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCF1 | c.1564G>A p.D522N (on ENST00000326195 / NM_001025091.2; = p.D484N on NM_001090.3) | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.459); catalogued as rs370944948; called by muse, mutect2, varscan2
- CEP95 | c.379del p.Q127Sfs*67 | Frame Shift Del (DEL) | VAF 23/64 reads (36%) | catalogued as COSV73608538; called by mutect2, pindel, varscan2
- COL6A3 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs745667305, COSV99798957; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPS1 | c.3010C>T p.R1004C | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs368206146; called by muse, mutect2, varscan2
- DNAH11 | c.12998C>T p.P4333L | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60937748; called by muse, mutect2, varscan2
- DSP | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 53/237 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761051181, CM157466, COSV65792342; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT4 | c.13578C>G p.I4526M | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV58690714; called by muse, mutect2, varscan2
- IGHV2-70 | c.147C>A p.S49R | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs376260160; called by muse, varscan2
- IGLV3-1 | c.340G>C p.A114P | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs368499668; called by muse, varscan2
- KATNIP | c.3616A>G p.I1206V | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.034); catalogued as rs1443786359; called by muse, mutect2, varscan2
- MAGEC2 | c.665A>C p.E222A | Missense Mutation (SNP) | VAF 53/53 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.263); catalogued as COSV55997596; called by muse, mutect2, varscan2
- PPP1R3A | c.1040T>C p.V347A | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as rs372606055; called by muse, mutect2, varscan2
- PRR14L | c.1796C>T p.P599L | Missense Mutation (SNP) | VAF 137/419 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1231586608; called by muse, mutect2, varscan2
- RBBP6 | c.2572G>A p.E858K | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.453); catalogued as COSV60504000; called by muse, mutect2, varscan2
- ROS1 | c.5249-1G>C p.X1750_splice | Splice Site (SNP) | VAF 7/35 reads (20%) | catalogued as rs962299629, COSV63857884; called by muse, mutect2, varscan2
- TLE2 | c.1942G>A p.G648R | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1454847287; called by muse, mutect2, varscan2
- USP24 | c.436C>G p.R146G | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1408844694; called by muse, mutect2, varscan2
- ACKR3 | c.818T>C p.L273P | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ADGRB1 | c.3421G>A p.V1141M | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2
- AFTPH | c.1170_1178del p.T391_F393del | In Frame Del (DEL) | VAF 72/226 reads (32%) | called by mutect2, pindel, varscan2
- ATP8B4 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- COL12A1 | c.7657T>C p.Y2553H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- CPD | c.3605G>A p.R1202K | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOK6 | c.350A>T p.N117I | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- EPB41L4B | c.1524_1529dup p.Q515_H516dup | In Frame Ins (INS) | VAF 14/90 reads (16%) | called by mutect2, varscan2
- EPHA6 | c.1217G>A p.C406Y | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FASLG | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- IL10 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- JMJD1C | c.5205A>T p.R1735S | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MDC1 | c.5044A>T p.K1682* | Nonsense Mutation (SNP) | VAF 29/174 reads (17%) | called by muse, mutect2, varscan2
- MYO16 | c.3893C>A p.P1298H | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NTRK3 | c.2020C>T p.H674Y | Missense Mutation (SNP) | VAF 52/207 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OR2H1 | c.284G>A p.C95Y | Missense Mutation (SNP) | VAF 81/166 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHAC2 | c.1058T>C p.V353A | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRR14L | c.1541C>T p.S514F | Missense Mutation (SNP) | VAF 123/373 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- PSMB6 | c.33del p.P13Qfs*52 | Frame Shift Del (DEL) | VAF 40/89 reads (45%) | called by mutect2, pindel, varscan2
- ROS1 | c.4930T>G p.W1644G | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RPS12 | c.234+1del | Frame Shift Del (DEL) | VAF 85/254 reads (33%) | called by mutect2, pindel, varscan2
- RYR2 | c.14337C>A p.Y4779* | Nonsense Mutation (SNP) | VAF 22/57 reads (39%) | called by muse, mutect2, varscan2
- SF1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 27/75 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- SLC5A1 | c.484A>T p.I162F | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2
- SLTM | c.2232_2234del p.N744del | In Frame Del (DEL) | VAF 32/117 reads (27%) | called by mutect2, pindel, varscan2
- SPRTN | c.1040A>G p.N347S | Missense Mutation (SNP) | VAF 10/333 reads (3%) | SIFT tolerated (0.57); PolyPhen benign (0.014); called by muse, mutect2
- STK17A | c.135G>C p.E45D | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.29); PolyPhen benign (0.063); called by muse, mutect2
- TMEM171 | c.49C>T p.H17Y | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- ZBTB43 | c.349G>C p.D117H | Missense Mutation (SNP) | VAF 54/235 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZMYM5 | c.1543C>T p.P515S | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF557 | c.175A>G p.T59A (on ENST00000414706 / NM_001044388.2; = p.T66A on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/215 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ARSJ | c.1311C>T p.G437= | Silent (SNP) | VAF 27/43 reads (63%) | called by muse, mutect2, varscan2
- ATP8B3 | c.3213C>T p.D1071= | Silent (SNP) | VAF 47/150 reads (31%) | catalogued as rs187141822; called by muse, mutect2, varscan2
- CEP20 | c.504T>C p.V168= | Silent (SNP) | VAF 6/116 reads (5%) | called by muse, mutect2
- FBXO28 | c.108C>T p.P36= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- GALNS | c.1497G>A p.P499= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs749979032; called by muse, mutect2, varscan2
- GLT1D1 | c.402C>T p.V134= | Silent (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.141A>G p.S47= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs576478313; called by muse, varscan2
- KHDRBS2 | c.513A>G p.Q171= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as rs375362715; called by muse, mutect2, varscan2
- NCDN | c.879C>T p.G293= | Silent (SNP) | VAF 33/126 reads (26%) | called by muse, mutect2, varscan2
- OR10G4 | c.681C>T p.I227= | Silent (SNP) | VAF 36/110 reads (33%) | catalogued as rs776884150; called by muse, mutect2, varscan2
- OR2T12 | c.36C>T p.L12= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs140902647; called by muse, mutect2, varscan2
- PPP6R1 | c.849C>T p.S283= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as rs370628730; called by muse, mutect2, varscan2
- PRUNE2 | c.6081G>A p.L2027= | Silent (SNP) | VAF 48/213 reads (23%) | catalogued as rs1479319358, COSV100944242, COSV100944406; called by muse, mutect2, varscan2
- AC092070.2 | n.2589_2592del | RNA (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- ADAMTS19 | c.*1445T>A | 3'UTR (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- AGBL5 | c.2355+337C>T | Intron (SNP) | VAF 38/121 reads (31%) | called by muse, mutect2, varscan2
- CAMK4 | c.*145T>C | 3'UTR (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2
- CCN3 | c.*1173G>A | 3'UTR (SNP) | VAF 9/15 reads (60%) | catalogued as rs1416535973; called by muse, mutect2
- CCSER2 | c.*2140A>C | 3'UTR (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- CDC37L1 | c.*673_*674del | 3'UTR (DEL) | VAF 22/83 reads (27%) | catalogued as rs1375134781; called by mutect2, pindel, varscan2
- CDK2AP2 | chr11:67508188 A>T | 5'Flank (SNP) | VAF 34/48 reads (71%) | called by muse, mutect2, varscan2
- CFAP20DC | chr3:59050055 C>A | 5'Flank (SNP) | VAF 29/66 reads (44%) | called by muse, mutect2, varscan2
- CHAT | c.-92C>T | 5'UTR (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
- CLEC4G | c.220+51T>C | Intron (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- CNTRL | c.-463A>C | 5'UTR (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- CPNE7 | c.1764+265C>T | Intron (SNP) | VAF 35/76 reads (46%) | catalogued as rs1185298553; called by muse, mutect2, varscan2
- CYB561A3 | c.*654C>G | 3'UTR (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- EFEMP1 | c.*1026C>G | 3'UTR (SNP) | VAF 23/73 reads (32%) | called by muse, mutect2, varscan2
- EXOC1 | c.1331-30C>T | Intron (SNP) | VAF 44/107 reads (41%) | called by muse, mutect2, varscan2
- EXT1 | c.-757G>A | 5'UTR (SNP) | VAF 10/96 reads (10%) | called by muse, mutect2, varscan2
- FAM53B | chr10:124618515 A>G | 3'Flank (SNP) | VAF 10/17 reads (59%) | called by muse, mutect2, varscan2
- FECH | c.-15G>A | 5'UTR (SNP) | VAF 12/45 reads (27%) | called by muse, mutect2, varscan2
- GAB4 | c.-73G>T | 5'UTR (SNP) | VAF 3/19 reads (16%) | catalogued as COSV68754494; called by muse, mutect2
- GABRA2 | c.1059+586C>A | Intron (SNP) | VAF 23/48 reads (48%) | catalogued as rs1385049980; called by muse, mutect2, varscan2
- KCNV1 | chr8:109966082 T>C | 3'Flank (SNP) | VAF 31/55 reads (56%) | called by muse, mutect2, varscan2
- KDM1B | chr6:18222327 G>T | 3'Flank (SNP) | VAF 25/83 reads (30%) | called by muse, mutect2, varscan2
- KIAA1958 | c.*673C>T | 3'UTR (SNP) | VAF 21/73 reads (29%) | catalogued as rs1350078472; called by muse, mutect2, varscan2
- LAMA2 | c.8075+29A>C | Intron (SNP) | VAF 58/82 reads (71%) | catalogued as COSV70354407; called by muse, mutect2, varscan2
- LAMTOR5 | chr1:110408010 C>T | 5'Flank (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2
- LINC02206 | n.381G>T | RNA (SNP) | VAF 56/280 reads (20%) | catalogued as rs745868236; called by muse, mutect2, varscan2
- LRRC74B | c.415+49C>A | Intron (SNP) | VAF 60/142 reads (42%) | called by muse, mutect2, varscan2
- MAGEH1 | c.*111_*112del | 3'UTR (DEL) | VAF 14/20 reads (70%) | called by mutect2, pindel, varscan2
- MAPK10 | c.-49+53C>T | Intron (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
- NFATC1 | c.1387-29T>A | Intron (SNP) | VAF 20/60 reads (33%) | called by muse, mutect2, varscan2
- NUAK1 | c.-392G>T | 5'UTR (SNP) | VAF 6/14 reads (43%) | catalogued as rs1261734457; called by muse, mutect2, varscan2
- OR51E2 | c.*758T>C | 3'UTR (SNP) | VAF 42/108 reads (39%) | called by muse, mutect2, varscan2
- PDE10A | c.*3060G>T | 3'UTR (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- PEX5L | c.-291C>A | 5'UTR (SNP) | VAF 113/248 reads (46%) | called by muse, mutect2, varscan2
- PLAT | c.*41C>T | 3'UTR (SNP) | VAF 25/45 reads (56%) | called by muse, mutect2, varscan2
- PPFIA1 | c.*698G>A | 3'UTR (SNP) | VAF 2/9 reads (22%) | called by muse, mutect2
- PRDM2 | c.*398G>T | 3'UTR (SNP) | VAF 47/126 reads (37%) | called by muse, mutect2, varscan2
- PRL | chr6:22297070 C>A | 5'Flank (SNP) | VAF 15/237 reads (6%) | called by muse, mutect2
- PROS1 | c.*642G>A | 3'UTR (SNP) | VAF 37/176 reads (21%) | called by muse, mutect2, varscan2
- RASA2 | c.*2489T>G | 3'UTR (SNP) | VAF 17/74 reads (23%) | called by muse, mutect2, varscan2
- RBM39 | c.51+283G>A | Intron (SNP) | VAF 27/52 reads (52%) | called by muse, mutect2, varscan2
- ROCK1P1 | n.798dup | RNA (INS) | VAF 20/64 reads (31%) | catalogued as rs1329866035; called by mutect2, varscan2
- SPI1 | c.493+557G>T | Intron (SNP) | VAF 6/126 reads (5%) | called by muse, mutect2
- SPTLC2 | c.*5650G>C | 3'UTR (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- STEAP4 | c.*6265C>T | 3'UTR (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2, varscan2
- STUM | c.*3305C>A | 3'UTR (SNP) | VAF 22/74 reads (30%) | called by muse, mutect2, varscan2
- TMC4 | chr19:54160143 G>A | 3'Flank (SNP) | VAF 22/94 reads (23%) | called by muse, mutect2, varscan2
- TNFSF11 | c.*946_*947dup | 3'UTR (INS) | VAF 3/25 reads (12%) | called by pindel, varscan2*
- TP63 | c.1350-5987G>A | Intron (SNP) | VAF 5/87 reads (6%) | called by muse, mutect2
- TTLL5 | c.3740+4341T>C | Intron (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- USH2A | c.15298-1048G>A | Intron (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- USP28 | c.57+641_57+642insTTA | Intron (INS) | VAF 15/54 reads (28%) | called by mutect2, pindel, varscan2
- YWHAH | c.87+2620G>A | Intron (SNP) | VAF 117/646 reads (18%) | called by muse, varscan2
- ZNF606 | chr19:58005495 T>C | 5'Flank (SNP) | VAF 56/167 reads (34%) | called by muse, mutect2, varscan2
- ZNF772 | c.*3454T>C | 3'UTR (SNP) | VAF 35/103 reads (34%) | called by muse, mutect2, varscan2
